Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-ABSF, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-ABSF-TTM1-A (Metastatic).

[page 1 of 12]
Lab Results

Surgical Pathology - Final result ([REDACTED]) +0
Narrative

Clinical Comments:

Clinical Diagnosis:

Most likely advanced stage primary lung carcinoma

PostOp:

Same

Specimen:

#1- MEDIASTINAL MASS FOR FROZEN SECTION; #2- LEVEL 3

Gross Description:

Received is a two-part specimen.

#1- The specimen consists of a pink tissue fragment measuring 0.7 cm and a smaller pink tissue fragment measuring 0.2 cm. The specimen is submitted entirely for frozen section diagnosis. The frozen section control is submitted in cassette 1.

#2- The specimen consists of multiple pink tissue fragments measuring 0.5 cc in aggregate. The specimen is submitted entirely in cassette 2.

[REDACTED] +0

Surgical Path Consultation:

#1- MALIGNANT TUMOR, FAVOR SMALL CELL CARCINOMA. (07)

Diagnosis:

#1- MEDIASTINAL MASS, BIOPSY WITH FROZEN SECTION:

-METASTATIC MALIGNANCY

CONSISTENT WITH SMALL CELL NEUROENDOCRINE CARCINOMA.

-CD56 IMMUNOSTAINING

IS RANDOMLY POSITIVE, CHROMOGRANIN WEAKLY POSITIVE.

-FINDINGS SUPPORT A

DIAGNOSIS OF SMALL CELL NEUROENDOCRINE CARCINOMA.

#2- LEVEL 3,

BIOPSY:

-METASTATIC MALIGNANCY AS DESCRIBED IN PART 1.

NOTE:

Case reviewed in quality assurance conference with [REDACTED]
he concurs with the diagnosis.

Code: 9

Snop: 8013, 8016

Signature on File: [REDACTED]

Imaging Results

XR Chest 2 Views - Final result [REDACTED]

-4

[page 2 of 12]
PATIENT NAME: [REDACTED]
BIRTH DATE: [REDACTED]
SEX: M
REQUESTING PHYS: [REDACTED]
ATTENDING PHYS: [REDACTED]
REASON: Cough
Chest pain, pleuritic

MED REC NO: [REDACTED]
SERVICE DATE: [REDACTED] -72
REPORT DATE: [REDACTED] -72
ORDER FROM: [REDACTED]
ORDER: [REDACTED]
TRANSCRIBED: [REDACTED] -64

Final

CT CHEST W IV CONTRAST

Study Result

CLINICAL HISTORY: Dyspnea on exertion. Pulmonary nodules. Chest pain.

CT CHEST WITH CONTRAST:

COMMENTS: No prior studies for comparison.

There is extensive lymphadenopathy in the chest. Specifically, there is a 2.6 x 3.1 cm. subcarinal lymph node. There is AP window lymphadenopathy, measuring up to 1.6 x 2.2 cm. There is right paratracheal lymphadenopathy, measuring 2.9 x 2.9 cm. There is right hilar lymphadenopathy, measuring 2.2 x 3.8 cm. There are right supraclavicular lymph nodes, measuring up to 1 x 1.4 cm. There is a large right infrahilar mass, measuring 4 x 4.9 cm. A portion of the mass appears to be invading the right pulmonary veins. There is a 1.5 cm. left upper lobe nodule. There is a 1.1 cm. right upper lobe nodule. There is some postobstructive atelectasis in the right middle lobe. Emphysematous changes in the upper lung zones. Upper abdominal images through the adrenal glands show a moderately sized hiatal hernia.

IMPRESSION:

Large right infrahilar mass with extensive metastatic lymphadenopathy to the mediastinum, as well as at least two other lung nodules. The findings are highly suspicious for lung carcinoma with metastatic lymphadenopathy and other lung metastases.

Results

-70 Scan on [REDACTED]: CONSENT ADMINISTRATION OF IV CONTRAST
-72 Dictation on [REDACTED]

This result has been Addended. See Addendum at the top of this result.

This study was interpreted by: [REDACTED]

[page 3 of 12]
This report has been reviewed and released by:

Signed by:

PACS Images

Show images for CT CHEST W IV CONTRAST

Patient Release Status:

This result is not viewable by the patient.

In Basket Reviewed

Discharge Instructions

None

Additional Order Information

Open Additional Information

Order

CT CHEST W IV CONTRAST

Order Providers

Authorizing

Encounter

Billing

Replaced: CT CHEST W IV CONTRAST

Order Information

Date

Department

Ordering/Authorizing

Start Date/Time

Start Date

In Basket Reviewed

Order-Level Documents:

Scan on : CONSENT ADMINISTRATION OF IV CONTRAST

Original Order

Ordered On

Ordered By

Order #

Release Information

Released On

Released By

Associated Diagnoses

Cough [786.2]

Chest pain, pleuritic [786.52]

Scheduling Instructions

Process Instructions

NO ORAL CONTRAST

[page 4 of 12]
The patient should have nothing to eat 4 hours prior to their exam at [REDACTED] and 6 hrs at [REDACTED].
Clear liquids only may be consumed during this time.

They are encouraged to drink plenty of water 24 hours before and after the appointment.

If the patient is 55 or over, they MUST have had a BUN and CREATININE lab tests done within the last 30 days. Prior results may be faxed to the department.

If diabetic, patient may have crackers or juice up to 1-2 hours prior to exam. This will help maintain a proper blood sugar insulin balance.

****If the patient states that they are allergic to IV contrast, they need to contact their physician. ****

[REDACTED] Their physician may have ordered a prescription for pre-medication. (Predisone and Benadryl)
The patient's physician needs to talk with the Radiologist about pre-medication regimen.

**** Please be aware that the CT machine has a 450 lb weight limit. We can not do patients that exceed that amount. ****

Order Questions

Question	Answer	Comment
Ordering Provider	[REDACTED]	

Appointments for this Order

Additional Information

Associated Reports	External References
View Encounter	ACR Appropriateness Criteria-Diagnostic Imaging
Priority and Order Details	

CT CHEST W IV CONTRAST

Ordering user:	[REDACTED] -88	Ordering provider:	[REDACTED]
Authorized by:	[REDACTED]	Ordering mode:	Standard
Electronically signed by:	[REDACTED] -88		
Diagnoses:	Cough [786.2] Chest pain, pleuritic [786.52]		

Authorizing Provider NPI information

Patient Release Status:

This result is not viewable by the patient.

Order Transmittal Tracking/Results Routing Info

Order Transmittal Tracking/Results Routing Info

Reprint Order

CT CHEST W IV CONTRAST
[REDACTED] -72

Additional Order Information

Open Additional Information

[page 5 of 12]
PATIENT NAME:
BIRTH DATE:
SEX:
REQUESTING PHYS:
ATTENDING PHYS:
REASON:

M

Lung cancer

MED REC NO:
SERVICE DATE:
REPORT DATE:
ORDER FROM:
ORDER:
TRANSCRIBED:

+130

+130

+130

Final

CT CHEST ABDOMEN PELVIS W IV CONTRAST

Study Result

RADIOLOGIST

CONTRAST ENHANCED CT SCAN OF THE CHEST, ABDOMEN AND PELVIS

(DLP 1030.2 mGycm)

CLINICAL HISTORY: History of lung carcinoma, follow up chemotherapy.

80 cc Optiray 350 was given intravenously for the postcontrast phase.

CHEST: The current study is reviewed in comparison to +63

The previously described right hilar mass shows no interval change in size. In the axial plane (image #34) it measures 28 x 10-mm as compared to the 28 x 10 mm in the prior study (image #52). The right paratracheal lymph node described previously could not be appreciated. Aortopulmonary window is clear. Thoracic aorta is normal in caliber. Moderate size hiatal hernia. Mild underlying emphysematous changes of centrilobular emphysema. Large bulla noted at the lung apices. The previously described well-circumscribed nodule in the right upper lobe, and a similar nodule in the left upper lobe with a central calcification, show no interval change.

The expansile lesion in the anterior lateral aspect of the left rib described previously, is stable and shows no change. There is no loss of vertebral height.

ABDOMEN AND PELVIS: The liver, stomach, spleen, pancreas, and adrenals are normal in size. Again, there is a moderate sized hiatal hernia. Gallbladder is visualized. Kidneys are unremarkable. The retroperitoneal space is clear. Abdominal aorta shows atherosclerotic changes without aneurysmatic dilatation. There is no bowel obstruction. A few scattered diverticula of the sigmoid colon. No free fluid in the abdomen or pelvis. Bone window settings show a sclerotic focus involving the left side of the L2 vertebral body, which is stable.

IMPRESSION:

1. The right hilar mass is stable and shows no change. There are two nodules in the left upper lobe and right upper lobe that are stable and show no interval change compared to the study of +63
2. Moderate size hiatal hernia.
3. The lytic, expansile lesion of the left fifth rib is stable and shows no change.

[page 6 of 12]
4. No interval change in the abdomen and pelvis compared to the prior study. Again, there is a sclerotic metastatic focus at the L2 vertebral body. The remainder of the examination is unremarkable.

Results

+130 Scan on [REDACTED] CONSENT FOR IV CONTRAST
+130 Scan on [REDACTED] ORDER-CONTRAST MEDIA

This study was interpreted by: [REDACTED]

This report has been reviewed and released by: [REDACTED]

PACS Images

Show images for CT CHEST ABDOMEN PELVIS W IV CONTRAST

Patient Release Status:

This result is not viewable by the patient.

In Basket Reviewed

+133 [REDACTED]

Discharge Instructions

None [REDACTED]

Additional Order Information

Open Additional Information

Order

CT CHEST ABDOMEN PELVIS W IV CONTRAST [REDACTED]

Order Providers

Authorizing [REDACTED]

Encounter [REDACTED]

Referring [REDACTED]

Order Information

+129

Date [REDACTED]

Department [REDACTED]

Ordering/Authorizing [REDACTED]

Start Date/Time

Start Date [REDACTED]

+130

In Basket Reviewed

Order-Level Documents:

+129 Scan on [REDACTED] ORDER-CONTRAST MEDIA
+130 Scan on [REDACTED] CONSENT FOR IV CONTRAST

Original Order

+129

Ordered On [REDACTED]

Ordered By [REDACTED]

Order # [REDACTED]

Release Information

Released On [REDACTED]

Released By [REDACTED]

[page 7 of 12]
Associated Diagnoses

Lung cancer [162.9]

Process Instructions

The patient needs to bring their picture I.D. (i.e. Driver's License), Social Security Card or number, and current insurance cards with them to their appointment.

The patient needs to bring a list of current medications with them.

The patient should have nothing to eat 4 hours prior to their exam at [REDACTED] and 6 hrs a [REDACTED]

Clear liquids only may be consumed during this time.

They are encouraged to drink plenty of water 24 hours before and after the appointment.

If the patient is 55 or over, they MUST have had a BUN and CREATININE lab tests done within the last 30 days.

If at all possible, please have LABS drawn prior to the day of scheduled procedure.

Prior results may be faxed to the department at [REDACTED]

If diabetic, patient may have crackers or juice up to 1-2 hours prior to exam. This will help maintain a proper blood sugar insulin balance.

ORAL CONTRAST:

[REDACTED] The patient needs to come 1 hour prior to the appointment time to drink oral contrast.

[REDACTED] If the patient is Pre-registered and have an order in the system or order is scanned in, then the patient goes to the Radiology main waiting room. The imaging clerk fills out contrast prescription and faxes prescription to Pharmacy. They will go over contrast instructions.

Contrast will be dispensed by the Pharmacy.

Processing Hours: Mon-Fri 830-4 Pick-Up Hours: Mon-Fri 830-4

Patient must report to Radiology Department for pick-up

OR the patient may be given oral contrast by their physician.

Patients should drink the oral prep 2 hrs prior to their exam unless they are given other directions by a provider.

Schedulers - Please be aware that some Abd/Pelvis exams DO NOT require oral contrast.

Call the department [REDACTED] prior to sending the pt for contrast if the exam is related to the kidneys or if you have any questions.

ADD-ONS: The patient needs to come 1 hour prior to the appointment time to drink oral contrast.

If the patient states that they are allergic to IV contrast, they need to contact their physician.

[REDACTED] Their physician may have ordered a prescription for pre-medication. (Predisone and Benadryl)

The patient's physician needs to talk with the Radiologist about pre-medication regimen.

Please be aware that the CT machine has a 450 lb weight limit. We can not do patients that exceed that amount.

Order Questions

Question	Answer	Comment
Ordering Provider	[REDACTED]	
What is the patient's weight in lbs?	75.932 kg (167 lb 6.4 oz)	

[page 8 of 12]
Note: If weight exceeds 250 lbs, have the nurse obtain girth

Appointments for this Order

+130

Additional Information

Associated Reports

View Encounter

Priority and Order Details

Collection Information.

External References

ACR Appropriateness Criteria-Diagnostic Imaging

Cosign Order Info

Action
Ordering

+129

Created on

Responsible
Provider

Signed by

Signed on

+126

CT CHEST ABDOMEN PELVIS W IV CONTRAST

Ordering user:

Authorized by:

Electronically
signed by:

Electronically
cosigned by:

Diagnoses: Lung cancer [162.9]

Ordering
provider:
Ordering
mode:

Standard

dering

Authorizing Provider NPI information

Patient Release Status:

This result is not viewable by the patient.

Order Transmittal Tracking/Results Routing Info

Order Transmittal Tracking/Results Routing Info

Reprint Order

CT CHEST ABDOMEN PELVIS W IV CONTRAST

+130

Additional Order Information

Open Additional Information

[page 9 of 12]
PATIENT NAME: [REDACTED]
BIRTH DATE: [REDACTED]
SEX: M
REQUESTING PHYS: [REDACTED]
ATTENDING PHYS: [REDACTED]
REASON: Lung cancer

MED REC NO: [REDACTED]
SERVICE DATE: [REDACTED] +957
REPORT DATE: [REDACTED] +957
ORDER FROM: [REDACTED]
ORDER: [REDACTED]
TRANSCRIBED: [REDACTED] +957

Final

CT CHEST ABDOMEN PELVIS W IV CONTRAST

Study Result

RADIOLOGIST: [REDACTED]

CT CHEST, ABDOMEN AND PELVIS WITH IV CONTRAST

(DLP 2532 mGy-cm)

REASON FOR EXAMINATION: Lung cancer followup.

Comparison is made to previous scan dated [REDACTED] +615

FINDINGS:

CHEST: There continues to be evidence of 3 lung nodules, all three stable from before. There is one in the right middle lobe, measuring about 1 cm, one in the left lingula, also measuring about 1 cm. There is a right hilar mass that measures 2.5 x 1.8 cm, probably unchanged, allowing for slight differences in measurement, location and technique. There is a third tiny nodule in the left lower lobe measuring 6 mm, which was also present on the previous study and is stable. There is no evidence of any enlarged mediastinal lymph nodes. A moderate size hiatal hernia is present, stable.

ABDOMEN: There is no liver lesions. There is no adrenal abnormality. Spleen is normal. Adrenal glands, pancreas and kidneys are within normal limits. Gallbladder is unremarkable.

PELVIS: Extensive diverticulosis is seen.

IMPRESSION:

1. Stable lung nodules. Right hilar lesion is also stable.
2. No change in bony metastases at L3 and left fifth rib.
3. There are no new metastatic foci.

Results +957

Scan on [REDACTED]: CONSENT ADMINISTRATION OF IV CONTRAST

Dictation on [REDACTED]

+957

[page 10 of 12]
This study was interpreted by:

This report has been reviewed and released by:

PACS Images

Show images for CT CHEST ABDOMEN PELVIS W IV CONTRAST

Patient Release Status:

This result is viewable by the patient in

In Basket Reviewed

Discharge Instructions

None

Additional Order Information

Open Additional Information

Order

CT CHEST ABDOMEN PELVIS W IV CONTRAST

Order Providers

Authorizing

Encounter

Billing

Order Information

Date

Department

Ordering/Authorizing

Start Date/Time

Start Date

Start Time

In Basket Reviewed

Order-Level Documents:

Scan on

CONSENT ADMINISTRATION OF IV CONTRAST

Original Order +957

Ordered On

Ordered By

Order #

Release Information

Released On

Released By

Associated Diagnoses

Lung cancer [162.9]

Process Instructions

The patient needs to bring their picture I.D. (i.e. Driver's License), Social Security Card or number, and current insurance cards with them to their appointment.

The patient needs to bring a list of current medications with them.

[page 11 of 12]
The patient should have nothing to eat 4 hours prior to their exam at [redacted] and 6 hrs at [redacted]. Clear liquids only may be consumed during this time.

They are encouraged to drink plenty of water 24 hours before and after the appointment.

If the patient is 55 or over, they MUST have had a BUN and CREATININE lab tests done within the last 30 days.

If at all possible, please have LABS drawn prior to the day of scheduled procedure.

Prior results may be faxed to the department at [redacted]

If diabetic, patient may have crackers or juice up to 1-2 hours prior to exam. This will help maintain a proper blood sugar insulin balance.

ORAL CONTRAST:

The patient needs to come 1 hour prior to the appointment time to drink oral contrast.

If the patient is Pre-registered and have an order in the system or order is scanned in, then the patient goes to the Radiology main waiting room. The imaging clerk fills out contrast prescription and faxes prescription to Pharmacy. They will go over contrast instructions.

Contrast will be dispensed by the Pharmacy.

Processing Hours: Mon-Fri 830-4 Pick-Up Hours: Mon-Fri 830-4

Patient must report to Radiology Department for pick-up

OR the patient may be given oral contrast by their physician.

Patients should drink the oral prep 2 hrs prior to their exam unless they are given other directions by a provider.

Schedulers - Please be aware that some Abd/Pelvis exams DO NOT require oral contrast.

Call the department [redacted] prior to sending the pt for contrast if the exam is related to the kidneys or if you have any questions.

ADD-ONS: The patient needs to come 1 hour prior to the appointment time to drink oral contrast.

If the patient states that they are allergic to IV contrast, they need to contact their physician.

Their physician may have ordered a prescription for pre-medication. (Predisone and Benadryl)
The patient's physician needs to talk with the Radiologist about pre-medication regimen.

Please be aware that the CT machine has a 450 lb weight limit. We can not do patients that exceed that amount.

Order Questions

Question	Answer	Comment
Ordering Provider	[redacted]	
What is the patient's weight in lbs?	90.175 kg (198 lb 12.8 oz) [redacted]	

Note: If weight exceeds 250 lbs, have the nurse obtain girth

Appointments for this Order

+957 [redacted]

Additional Information

Associated Reports	External References
View Encounter	ACR Appropriateness Criteria-Diagnostic Imaging
Priority and Order Details	

[page 12 of 12]
Collection Information.

Verbal Order Information

Action	Created on	Order Mode	Entered by	Comment	Responsible Provider	Signed by	Signed
Ordering	[REDACTED] +955	Verbal with readback	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED] +956

CT CHEST ABDOMEN PELVIS W IV CONTRAST +955

Ordering user:	[REDACTED]	Ordering provider:	[REDACTED]
Authorized by:	[REDACTED]	Ordering mode:	Verbal with readback
Electronically signed by:	[REDACTED]		
Diagnoses:	Lung cancer [162.9]		

Authorizing Provider NPI information

Patient Release Status:

This result is viewable by the patient in [REDACTED]

Order Transmittal Tracking/Results Routing Info

Order Transmittal Tracking/Results Routing Info

Reprint Order

CT CHEST ABDOMEN PELVIS W IV CONTRAST
[REDACTED] +957

Additional Order Information

Open Additional Information

Source: NCI Genomic Data Commons file 47f4695c-fa1e-42f6-b3fd-3a36d5df6138 (ER0118 ER-ABSF Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).